Somatic mutation profile of tumor specimen TCGA-FG-6689-01A (aliquot TCGA-FG-6689-01A-11D-1893-08) from TCGA case TCGA-FG-6689, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.0 years (11,312 days).
Specimen TCGA-FG-6689-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6191d3fc-bdb9-415b-a436-5dd5497d27cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-6689-10A (Blood Derived Normal), aliquot TCGA-FG-6689-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae142fb0-7ccc-4d72-979a-f255c5ab5c2b

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Intron 1, Frame Shift Del 1, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 24/81 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.97dup p.S33Ffs*10 | Frame Shift Ins (INS) | VAF 108/352 reads (31%) | catalogued as rs1131691041, COSV52680743, COSV99383879; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANTXR1 | c.721G>A p.V241M | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs931085101, COSV58011104; called by muse, mutect2
- ATRX | c.4160C>G p.S1387* | Nonsense Mutation (SNP) | VAF 25/40 reads (63%) | catalogued as COSV64873705; called by muse, mutect2, varscan2
- CA1 | c.494T>C p.L165P | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56277977; called by muse, mutect2, varscan2
- DIXDC1 | c.1459A>T p.N487Y (on ENST00000440460 / NM_001037954.4; = p.N276Y on NM_033425.4) | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV59461481; called by muse, mutect2, varscan2
- KIF23 | c.337G>A p.V113M | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52978350; called by muse, mutect2, varscan2
- MET | c.1901T>C p.F634S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV59258992; called by muse, mutect2, varscan2
- S1PR5 | c.1162G>A p.A388T | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1394898768, COSV61013494; called by muse, mutect2, varscan2
- SULF1 | c.974G>C p.G325A | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52677204; called by muse, mutect2
- TP53 | c.339_341del p.F113del | In Frame Del (DEL) | VAF 30/100 reads (30%) | catalogued as rs764486868; called by pindel, varscan2
- TRIM7 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.025); catalogued as COSV51240875, COSV51250378; called by muse, mutect2
- TSHZ1 | c.710G>A p.G237D (on ENST00000580243 / NM_001308210.2; = p.G192D on NM_005786.6) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59007473; called by muse, mutect2
- ZNF827 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65225827, COSV65226502; called by muse, mutect2, varscan2
- KATNA1 | c.110del p.N37Tfs*23 | Frame Shift Del (DEL) | VAF 67/268 reads (25%) | called by mutect2, pindel, varscan2
- ACP2 | c.807C>T p.T269= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV57037612; called by muse, mutect2
- MDC1 | c.2124G>A p.L708= | Silent (SNP) | VAF 9/168 reads (5%) | catalogued as COSV64523903; called by muse, mutect2
- MRGBP | c.228C>G p.V76= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV65111345; called by muse, mutect2, varscan2
- PLCB1 | c.990G>A p.S330= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as rs375950955; ClinVar: likely benign; called by muse, mutect2
- FYB1 | c.1907+1655T>C | Intron (SNP) | VAF 27/58 reads (47%) | catalogued as rs765797489, COSV100685236; called by muse, mutect2, varscan2
